Somatic mutation profile of tumor specimen TCGA-5U-AB0E-01A (aliquot TCGA-5U-AB0E-01A-11D-A423-09) from TCGA case TCGA-5U-AB0E, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B3, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 62.2 years (22,716 days).
Specimen TCGA-5U-AB0E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bcf4b56-d22c-4048-8d34-bb0dde32a665.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5U-AB0E-10A (Blood Derived Normal), aliquot TCGA-5U-AB0E-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b59ca578-7142-4cd6-852e-468698a13f8c

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Frame Shift Del 2, Splice Site 1, Silent 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CERKL | c.974-1G>A p.X325_splice (on ENST00000339098 / NM_001030311.2; = p.X299_splice on NM_201548.5) | Splice Site (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100183797; called by muse, mutect2, varscan2
- CHD2 | c.3377A>G p.D1126G | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs1343182559; called by muse, mutect2, varscan2
- COQ8B | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs960492727, COSV99424860; called by muse, mutect2, varscan2
- SLC13A1 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1018277828; called by muse, mutect2, varscan2
- SLC16A3 | c.797T>A p.L266Q | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99061435; called by muse, mutect2, varscan2
- AC011455.2 | c.1089T>A p.D363E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ANKMY1 | c.1424G>A p.C475Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BBS9 | c.2224C>A p.Q742K (on ENST00000242067 / NM_001348036.1; = p.Q702K on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.553); called by muse, mutect2
- GAK | c.2048T>A p.F683Y | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GRM4 | c.83del p.P28Lfs*13 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel, varscan2
- OTUD4 | c.406C>G p.P136A (on ENST00000447906 / NM_001366057.1; = p.P71A on NM_017493.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.075); called by muse, mutect2
- SPEG | c.2683del p.E895Sfs*9 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- HOXA1 | c.630C>T p.V210= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- FAM169B | n.416T>C | RNA (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- KLK8 | c.71-47G>A | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as rs765512862; called by muse, mutect2, varscan2
